Somatic mutation profile of tumor specimen C3L-01955-01 (aliquot CPT0389780006) from CPTAC case C3L-01955, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oncocytoma; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: GX; Age at diagnosis: 67.1 years (24,505 days).
Specimen C3L-01955-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef73d751-061a-4a2d-9582-42816b4e4977.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01955-31 (Blood Derived Normal), aliquot CPT0389840002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1568d69c-8ac4-42ad-949e-76e7a85a1005

The open-access MAF lists 28 somatic variants for this specimen: 14 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 12, Missense Mutation 10, Nonsense Mutation 2, 5'UTR 1, In Frame Del 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRD4 | c.655C>T p.Q219* | Nonsense Mutation (SNP) | VAF 69/183 reads (38%) | catalogued as COSV54585774, COSV54591904; called by muse, mutect2, varscan2
- MAGEA8 | c.784C>T p.R262C | Missense Mutation (SNP) | VAF 58/140 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as rs929885088, COSV54063682; called by muse, mutect2, varscan2
- NLRP13 | c.1153G>T p.G385W | Missense Mutation (SNP) | VAF 76/217 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140199811, COSV61623938; called by muse, mutect2, varscan2
- PLA2G6 | c.1116C>G p.F372L | Missense Mutation (SNP) | VAF 216/498 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59273828; called by muse, mutect2, varscan2
- SPTBN1 | c.2365G>A p.V789M | Missense Mutation (SNP) | VAF 158/388 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as rs957422145, COSV61691544, COSV61692376; called by muse, mutect2, varscan2
- COL5A3 | c.1422+1G>A p.X474_splice | Splice Site (SNP) | VAF 8/128 reads (6%) | called by muse, mutect2
- EGFR | c.541C>T p.Q181* | Nonsense Mutation (SNP) | VAF 149/431 reads (35%) | called by muse, mutect2, varscan2
- IL17RD | c.1557G>T p.Q519H | Missense Mutation (SNP) | VAF 9/220 reads (4%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2
- LRRK2 | c.5941G>A p.G1981S | Missense Mutation (SNP) | VAF 10/300 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NAIF1 | c.347G>A p.G116D | Missense Mutation (SNP) | VAF 45/94 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- ORM2 | c.20T>G p.L7R | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OSBPL2 | c.123T>G p.N41K (on ENST00000313733 / NM_144498.4; = p.N29K on NM_014835.4) | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0.013); called by muse, mutect2
- PLAG1 | c.1103C>G p.P368R | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- SF3B1 | c.2938_2943del p.E980_Y981del | In Frame Del (DEL) | VAF 55/191 reads (29%) | called by mutect2, pindel, varscan2
- BHMG1 | c.1296C>T p.H432= | Silent (SNP) | VAF 7/106 reads (7%) | called by muse, mutect2
- CCDC168 | c.11454A>T p.S3818= | Silent (SNP) | VAF 37/87 reads (43%) | called by muse, mutect2, varscan2
- COG5 | c.1389C>T p.F463= | Silent (SNP) | VAF 59/166 reads (36%) | catalogued as rs748974685, COSV51763383; called by muse, mutect2, varscan2
- GHR | c.624C>T p.D208= | Silent (SNP) | VAF 79/216 reads (37%) | called by muse, mutect2, varscan2
- MTMR1 | c.1197G>T p.R399= | Silent (SNP) | VAF 25/63 reads (40%) | called by muse, mutect2, varscan2
- MYO1C | c.492C>A p.P164= (on ENST00000648651 / NM_001080779.2; = p.P129= on NM_033375.5) | Silent (SNP) | VAF 116/311 reads (37%) | catalogued as rs774487926, COSV100704470, COSV63001187; called by muse, mutect2, varscan2
- SDK2 | c.6246A>G p.T2082= | Silent (SNP) | VAF 154/422 reads (36%) | catalogued as rs369723791; called by muse, mutect2, varscan2
- SLC1A7 | c.927C>T p.L309= | Silent (SNP) | VAF 28/408 reads (7%) | called by muse, mutect2
- TTN | c.36564C>T p.G12188= (on ENST00000591111; = p.G4764= on NM_003319.4) | Silent (SNP) | VAF 36/96 reads (38%) | catalogued as rs531726095, COSV60127910; ClinVar: likely benign; called by muse, mutect2, varscan2
- UNC45B | c.1641C>T p.D547= | Silent (SNP) | VAF 18/184 reads (10%) | called by muse, mutect2
- WNK1 | c.715C>T p.L239= | Silent (SNP) | VAF 24/312 reads (8%) | called by muse, mutect2
- ZAN | c.177C>T p.D59= | Silent (SNP) | VAF 147/444 reads (33%) | catalogued as rs1201262758, COSV61805517; called by muse, mutect2, varscan2
- D2HGDH | c.1141-656G>A | Intron (SNP) | VAF 44/105 reads (42%) | catalogued as rs755964303; called by muse, mutect2, varscan2
- TNN | c.-97G>A | 5'UTR (SNP) | VAF 68/284 reads (24%) | catalogued as rs781614761, COSV53421431; called by muse, mutect2, varscan2
